FM case AD16702 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract.
https://portal.gdc.cancer.gov/cases/12f3927f-d1e0-4e0f-a850-07e86d8945cd

Female, 71.1 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the biliary tract; metastasis biopsied or resected from the extrahepatic bile duct. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
